CCDI case PBBVXF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/4e83b131-2f87-420a-9bc6-543111b5d84a

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 14.6 years (5,335 days).

Biospecimens (3 samples)
- Sample 0DIZVT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIZVW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIZWC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
